Somatic mutation profile of tumor specimen ALCH-B5E1-TTP1-A (aliquot ALCH-B5E1-TTP1-A-1-0-D-A83F-36) from ALCHEMIST case ALCH-B5E1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.2 years (25,291 days).
Specimen ALCH-B5E1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15152a08-7c02-4abf-9a01-538734ee05d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B5E1-NB1-A (Blood Derived Normal), aliquot ALCH-B5E1-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6174b630-9340-442b-aa14-b44cae9b6c62

The open-access MAF lists 53 somatic variants for this specimen: 29 protein-altering or splice-affecting, 17 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 17, Intron 4, 5'Flank 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ECEL1 | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs587776919, CM130310, CM130313, COSV100458737; ClinVar: pathogenic; called by muse, mutect2
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 158/914 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.7496C>A p.P2499H (on ENST00000646647 / NM_001170629.2; = p.P2220H on NM_020920.4) | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1212151127; ClinVar: uncertain significance; called by muse, mutect2
- FKBP6 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 64/996 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs782734911; called by muse, mutect2
- GLB1L | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 28/709 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV55476094; called by muse, mutect2
- LRFN5 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 19/238 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.148); catalogued as rs1051039315, COSV53243316, COSV53273551; called by muse, mutect2
- PCDHB10 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 86/670 reads (13%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.021); catalogued as COSV53375036; called by muse, mutect2, varscan2
- PCLO | c.10674G>C p.K3558N | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.203); catalogued as COSV61653900, COSV61661455; called by muse, mutect2
- RNF2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 34/630 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62279283; called by muse, mutect2
- SOX4 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 40/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99782078; called by muse, mutect2, varscan2
- TBXAS1 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 98/987 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs141602429; called by muse, mutect2
- TFAP2D | c.919A>G p.T307A | Missense Mutation (SNP) | VAF 13/330 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs999553831; called by muse, mutect2
- ZNF479 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 34/940 reads (4%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.062); catalogued as COSV58638477; called by muse, mutect2
- ZNF646 | c.4376C>T p.A1459V | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1270387145; called by muse, mutect2
- ANK1 | c.2174C>A p.A725E | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- BCKDK | c.872C>G p.T291S | Missense Mutation (SNP) | VAF 39/352 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- COL11A2 | c.1892G>T p.G631V (on ENST00000341947 / NM_080680.3; = p.G524V on NM_080679.2) | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FNDC1 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); called by muse, mutect2
- LMTK2 | c.3052C>T p.P1018S | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- MUC16 | c.656A>C p.D219A | Missense Mutation (SNP) | VAF 15/482 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.079); called by muse, mutect2
- PPP1R26 | c.1630C>G p.L544V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- QSER1 | c.1730C>G p.S577C (on ENST00000399302; = p.S706C on NM_001076786.3) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- REV3L | c.6596T>C p.F2199S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- RHAG | c.634A>T p.M212L | Missense Mutation (SNP) | VAF 46/804 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.143); called by muse, mutect2
- RTN1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- SCN5A | c.3668C>T p.A1223V (on ENST00000333535 / NM_198056.3; = p.A1222V on NM_000335.5) | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); called by muse, mutect2
- TRMT1 | c.1553C>A p.P518Q | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- UFL1 | c.1526T>G p.L509R | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF14 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2
- ABCA13 | c.3183T>G p.T1061= | Silent (SNP) | VAF 51/454 reads (11%) | called by muse, mutect2, varscan2
- ARID3B | c.639C>T p.D213= | Silent (SNP) | VAF 16/186 reads (9%) | catalogued as rs201179649, COSV60558168; called by muse, mutect2
- CACNA1C | c.1452C>T p.I484= | Silent (SNP) | VAF 21/359 reads (6%) | catalogued as rs1432858631, COSV100215118; called by muse, mutect2
- HRH2 | c.240G>T p.L80= | Silent (SNP) | VAF 20/414 reads (5%) | catalogued as COSV51576766; called by muse, mutect2
- INTS2 | c.2916C>A p.T972= | Silent (SNP) | VAF 11/251 reads (4%) | called by muse, mutect2
- KLHL36 | c.921G>T p.R307= | Silent (SNP) | VAF 36/227 reads (16%) | called by muse, mutect2, varscan2
- LRFN1 | c.753C>A p.G251= | Silent (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2, varscan2
- LTV1 | c.657C>T p.P219= | Silent (SNP) | VAF 42/729 reads (6%) | catalogued as rs199589018; called by muse, mutect2
- MYH7B | c.3297C>T p.A1099= | Silent (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2
- OBSCN | c.19488C>A p.A6496= | Silent (SNP) | VAF 104/646 reads (16%) | called by muse, mutect2, varscan2
- PCDH17 | c.3249G>A p.K1083= | Silent (SNP) | VAF 12/363 reads (3%) | catalogued as rs1157654787; called by muse, mutect2
- PCDHB6 | c.1590C>T p.G530= | Silent (SNP) | VAF 42/1298 reads (3%) | catalogued as COSV50692466; called by muse, mutect2
- PPP1R2C | c.213C>T p.P71= | Silent (SNP) | VAF 13/264 reads (5%) | catalogued as rs1378021627; called by muse, mutect2
- PVRIG | c.393C>G p.T131= | Silent (SNP) | VAF 15/362 reads (4%) | called by muse, mutect2
- RUSC2 | c.2836C>T p.L946= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- SCN10A | c.987T>C p.S329= | Silent (SNP) | VAF 10/84 reads (12%) | called by muse, mutect2, varscan2
- WDR59 | c.1476G>A p.E492= | Silent (SNP) | VAF 44/320 reads (14%) | called by muse, mutect2, varscan2
- DPY19L2P2 | n.2891G>T | RNA (SNP) | VAF 17/227 reads (7%) | called by muse, mutect2, varscan2
- HNRNPM | c.284-21C>G | Intron (SNP) | VAF 35/260 reads (13%) | called by muse, mutect2, varscan2
- IFIT5 | chr10:89412816 C>A | 5'Flank (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- NUDCD3 | c.786+1751C>A | Intron (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- PRDM10 | chr11:130003414 C>G | 5'Flank (SNP) | VAF 13/130 reads (10%) | called by muse, mutect2
- RXYLT1 | c.325+1407A>T | Intron (SNP) | VAF 42/665 reads (6%) | called by muse, mutect2
- SPRED2 | c.27-32780T>A | Intron (SNP) | VAF 21/479 reads (4%) | called by muse, mutect2
